Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A958, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A958-01A (Primary Tumor).

ICD O. 3

Carcinoma, squamous cell
non-keratinizing NOS 8672/3

Site: Cervix NOS C53.9

JW 3/12/14

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

“Uterine cervix biopsy”:

Squamous cell carcinoma, moderately differentiated, invasive, non-keratinizing.

Criteria	JW 11/17/13	Yes	No

Source: NCI Genomic Data Commons file 16293f03-b2ef-4a34-975d-7b821e24491c (TCGA-VS-A958.643CD93E-47D0-4D40-96C8-DDF836EEF501.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).